Somatic mutation profile of tumor specimen C3L-02557-02 (aliquot CPT0128610006) from CPTAC case C3L-02557, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 60.9 years (22,238 days).
Specimen C3L-02557-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f0998ce-32c2-4e0c-a97b-cfcd0cede9bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02557-31 (Blood Derived Normal), aliquot CPT0129430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ccfb991-6312-46a5-babb-b0cfda52b43a

The open-access MAF lists 12,888 somatic variants for this specimen: 9,354 protein-altering or splice-affecting, 1,989 silent, 1,545 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,794, Silent 1,989, Nonsense Mutation 1,274, Intron 771, 3'UTR 275, RNA 242, Splice Site 165, 5'UTR 111, Splice Region 90, 5'Flank 74, 3'Flank 71, Frame Shift Ins 15.

Variants (750 of 12,888; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAAS | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 206/540 reads (38%) | catalogued as rs121918547, CM002928, COSV52932904; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.3196C>T p.R1066* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs780163791, COSV99663785; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARG1 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as rs747579073; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, varscan2
- ATP8A2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs1304109530, COSV54935035; ClinVar: likely pathogenic; called by muse, varscan2
- BMPR2 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs1085307162, CM043448, COSV101001852; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as rs80357426, CM044210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1064794263, CM065992, COSV64194216, COSV64200368; ClinVar: likely pathogenic; called by muse, varscan2
- CASR | c.1808G>A p.R603H (on ENST00000490131; = p.R680H on NM_000388.4) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773146939, CM002581; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as rs896947430, COSV67502337; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNA2 | c.2788C>T p.R930* (on ENST00000402739 / NM_001282597.3; = p.R882* on NM_004389.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as rs760139097, COSV58133839, COSV58164977; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 95/291 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNND2 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 57/174 reads (33%) | catalogued as rs886041494, COSV100481426; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2, varscan2
- DSP | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 79/285 reads (28%) | catalogued as rs1131691673, COSV65791931; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EFHC1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 140/262 reads (53%) | catalogued as rs796052414, COSV100932128; ClinVar: pathogenic; called by muse, varscan2
- FAM20A | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 98/284 reads (35%) | catalogued as rs144411158, CM112966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXL4 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs754142863, CM159511, CM159512, COSV100014015; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- FGFR1 | c.1042G>A p.G348R (on ENST00000447712 / NM_023110.3; = p.G346R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886037634, CM103835, COSV100248113; ClinVar: pathogenic / risk factor; called by muse, mutect2
- GABRA1 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs796052493, CM163312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by muse, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 42/58 reads (72%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.2737-1G>T p.X913_splice | Splice Site (SNP) | VAF 32/93 reads (34%) | catalogued as rs1553398334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MCCC2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 51/186 reads (27%) | catalogued as rs774180632, CM164493; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFAF2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as rs137852863, CM053986, COSV56942088; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NDUFS1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 70/240 reads (29%) | catalogued as rs750971390, COSV51907881, COSV99260518; ClinVar: pathogenic; called by muse, varscan2
- NEXMIF | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as rs1556016731, CM156012, COSV50023631; ClinVar: pathogenic; called by muse, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 124/232 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853260, CM981410, COSV63980092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as rs312262810, CM010945, COSV60794563; ClinVar: pathogenic; called by muse, mutect2
- PAH | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs62642945, CM961079, COSV100188508, COSV61015366; ClinVar: likely pathogenic / not provided; called by muse, varscan2
- PAX6 | c.357+1G>A p.X119_splice | Splice Site (SNP) | VAF 120/398 reads (30%) | catalogued as rs398123295, CD152674, CS930856, CS982310, CS993994, COSV53792430; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 107/262 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POMGNT1 | c.636C>T p.F212= | Silent (SNP) | VAF 281/677 reads (42%) | catalogued as rs190057175, CS075210; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 75/100 reads (75%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.5614C>T p.R1872W | Missense Mutation (SNP) | VAF 237/630 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053228, CM147204, COSV61987040, COSV99050261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPATA7 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as rs140287375, CM113103, COSV50417544; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SUZ12 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1443094716, COSV59498812; called by muse, mutect2, varscan2
- TNR | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs892080402, COSV54899846, COSV54900270; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 131/362 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TRPV4 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 164/423 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs387906902, CM108438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TTN | c.85774C>T p.R28592* (on ENST00000591111; = p.R21168* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs1553539391, COSV60169898; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1383516092; called by muse, mutect2, varscan2
- A2ML1 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs368671138; called by muse, mutect2, varscan2
- AASDH | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV52705847, COSV99221215; called by muse, varscan2
- AASDHPPT | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs751784261; called by muse, mutect2
- AASS | c.1456C>A p.L486I | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV62789414; called by muse, mutect2, varscan2
- AATK | c.3242C>A p.P1081Q (on ENST00000326724 / NM_001080395.3; = p.P978Q on NM_004920.2) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.162); catalogued as rs773490833; called by muse, mutect2, varscan2
- ABCA10 | c.3668G>T p.R1223I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52229274; called by muse, mutect2, varscan2
- ABCA10 | c.3422G>T p.G1141V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99288374; called by muse, mutect2, varscan2
- ABCA10 | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52218066; called by muse, mutect2
- ABCA10 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV104393371; called by muse, mutect2
- ABCA12 | c.4544G>A p.R1515Q (on ENST00000272895 / NM_173076.3; = p.R1197Q on NM_015657.3) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs774279263, CM1311790, COSV55948366; called by muse, mutect2, varscan2
- ABCA12 | c.949A>C p.K317Q | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as COSV55965205; called by muse, varscan2
- ABCA13 | c.2572A>G p.N858D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV101329960; called by muse, mutect2, varscan2
- ABCA13 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV70026130, COSV70027603; called by muse, mutect2, varscan2
- ABCA13 | c.6202G>T p.D2068Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV70028333; called by muse, mutect2, varscan2
- ABCA13 | c.7798G>T p.E2600* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV71285244, COSV71296255; called by muse, varscan2
- ABCA13 | c.12801G>T p.E4267D | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs757737367; called by muse, mutect2
- ABCA13 | c.14183G>A p.R4728Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs766502956, COSV68943781; called by muse, varscan2
- ABCA4 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.08); catalogued as COSV64675749; called by muse, varscan2
- ABCA5 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs1180912574, COSV101201128; called by muse, mutect2
- ABCA6 | c.3992G>T p.R1331I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV52644527, COSV99446466; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, mutect2, varscan2
- ABCA6 | c.2105G>T p.R702I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV52645451; called by muse, varscan2
- ABCA8 | c.4601G>A p.S1534N | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs967764031; called by muse, mutect2, varscan2
- ABCA8 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.026); catalogued as rs768333090, COSV52197981; called by muse, mutect2, varscan2
- ABCA8 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as rs1330548847, COSV99286863; called by muse, varscan2
- ABCA9 | c.3722C>A p.S1241Y | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV60620133; called by muse, mutect2, varscan2
- ABCB4 | c.1356+1G>T p.X452_splice | Splice Site (SNP) | VAF 127/385 reads (33%) | catalogued as COSV55931724; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB5 | c.2923G>A p.A975T (on ENST00000404938 / NM_001163941.2; = p.A530T on NM_178559.6) | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.206); catalogued as rs987731194, COSV51723244; called by muse, mutect2, varscan2
- ABCB8 | c.1565G>A p.R522H (on ENST00000297504 / NM_001282291.2; = p.R505H on NM_007188.5) | Missense Mutation (SNP) | VAF 133/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373159314; called by muse, mutect2, varscan2
- ABCC1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV60694395; called by muse, mutect2, varscan2
- ABCC12 | c.2075G>T p.R692I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV60916486; called by muse, mutect2, varscan2
- ABCC5 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.605); catalogued as rs766169066, COSV99657506; called by muse, mutect2, varscan2
- ABCC8 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs758995284, COSV56858022; called by muse, mutect2, varscan2
- ABCC9 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 26/75 reads (35%) | catalogued as COSV53983907; called by muse, varscan2
- ABCC9 | c.1181A>T p.K394I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV53971300; called by muse, varscan2
- ABCC9 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1212315529, COSV53966264; called by muse, mutect2, varscan2
- ABCD2 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.531); catalogued as rs770550941, COSV58053942; called by muse, mutect2, varscan2
- ABCD2 | c.1570C>A p.L524I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV58053444, COSV58055150; called by muse, mutect2, varscan2
- ABCD2 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 17/171 reads (10%) | catalogued as COSV58054366; called by muse, mutect2
- ABCF3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV99490888; called by muse, mutect2, varscan2
- ABCG8 | c.1841A>C p.K614T | Missense Mutation (SNP) | VAF 161/431 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99699401; called by muse, mutect2, varscan2
- ABHD18 | c.410G>A p.R137Q (on ENST00000398965 / NM_001039717.2; = p.R10Q on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs766702105; called by muse, mutect2
- ABI3BP | c.2804C>A p.S935Y | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52531925; called by muse, mutect2, varscan2
- ABLIM2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs771456940, COSV99589460; called by muse, mutect2, varscan2
- ABRAXAS1 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58947910, COSV58949040; called by mutect2, varscan2
- ABTB2 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.285); catalogued as rs1337694400, COSV100131790; called by muse, mutect2, varscan2
- AC004593.2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 178/500 reads (36%) | catalogued as COSV56089052; called by muse, mutect2, varscan2
- AC092143.1 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 104/529 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs755600316; called by muse, mutect2, varscan2
- AC134980.2 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60909154; called by muse, mutect2, varscan2
- ACACA | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1223416494; called by muse, mutect2, varscan2
- ACACB | c.6941C>T p.S2314F | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100623033; called by muse, mutect2, varscan2
- ACADL | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs375084422, CM112334, COSV52052059, COSV52052222; called by muse, mutect2, varscan2
- ACAN | c.7131G>T p.E2377D (on ENST00000560601 / NM_001369268.1; = p.E2301D on NM_001135.3) | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as rs754450944; called by muse, varscan2
- ACE2 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs764661406, COSV53024833; called by muse, varscan2
- ACER3 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV99568344; called by muse, mutect2
- ACKR1 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.303); catalogued as COSV63672700; called by muse, mutect2, varscan2
- ACLY | c.573C>A p.F191L | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61251622; called by muse, mutect2, varscan2
- ACLY | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1555634052, COSV61251371; called by muse, varscan2
- ACLY | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 41/151 reads (27%) | catalogued as COSV104418801; called by muse, varscan2
- ACO1 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 116/204 reads (57%) | catalogued as rs1028702991; called by muse, mutect2, varscan2
- ACOX2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs538107717; called by muse, mutect2, varscan2
- ACP2 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745500880, COSV57037091; called by muse, mutect2, varscan2
- ACRBP | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 124/321 reads (39%) | catalogued as rs778084989, COSV57523600; called by muse, mutect2, varscan2
- ACSBG2 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV53123339; called by muse, mutect2
- ACSL1 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs776443640, COSV55663688; called by muse, mutect2, varscan2
- ACSM2A | c.383G>A p.R128Q (on ENST00000219054; = p.R49Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770257438, COSV54583992; called by muse, mutect2, varscan2
- ACSM2B | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV61660225; called by muse, mutect2, varscan2
- ACSM4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV68066592; called by muse, mutect2, varscan2
- ACSM6 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1287415430, COSV58980945; called by muse, mutect2, varscan2
- ACTBL2 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs766164059; called by muse, mutect2, varscan2
- ACTC1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV51758756; called by muse, mutect2, varscan2
- ACTN2 | c.2621G>T p.S874I | Missense Mutation (SNP) | VAF 223/513 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1285035538; called by muse, mutect2, varscan2
- ACVR2A | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54020088; called by muse, mutect2, varscan2
- ACY3 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 50/676 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54829840; called by muse, mutect2
- ADAM17 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV60400554; called by muse, mutect2, varscan2
- ADAM18 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55847632; called by muse, mutect2, varscan2
- ADAM18 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV55844392; called by muse, mutect2, varscan2
- ADAM23 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as COSV52209973; called by muse, mutect2, varscan2
- ADAM30 | c.1496G>A p.G499E | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV65561117; called by muse, mutect2, varscan2
- ADAM33 | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.998); catalogued as COSV62935853; called by muse, mutect2, varscan2
- ADAM9 | c.608G>T p.R203I | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV65946824; called by muse, varscan2
- ADAM9 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 54/149 reads (36%) | catalogued as COSV65960601; called by muse, mutect2, varscan2
- ADAMTS12 | c.2392C>A p.L798I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs901072576; called by muse, mutect2, varscan2
- ADAMTS14 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs941719041; called by muse, mutect2, varscan2
- ADAMTS17 | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs778582648; called by muse, mutect2, varscan2
- ADAMTS17 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as rs746864724, COSV99171576; called by muse, mutect2, varscan2
- ADAMTS18 | c.1187C>A p.S396Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753774784; called by muse, mutect2, varscan2
- ADAMTS2 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 111/360 reads (31%) | catalogued as COSV52378623; called by muse, mutect2, varscan2
- ADAMTS20 | c.2279A>C p.D760A | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101166094; called by muse, mutect2, varscan2
- ADAMTS20 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs780153600, COSV67137622; called by muse, mutect2, varscan2
- ADAMTS3 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 26/44 reads (59%) | catalogued as COSV54390949; called by muse, mutect2
- ADAMTS3 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 96/211 reads (45%) | catalogued as rs1277436309, COSV54386590; called by muse, mutect2, varscan2
- ADAMTS3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99711788; called by muse, mutect2, varscan2
- ADAMTS7 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV101182980; called by muse, mutect2, varscan2
- ADAMTS7 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746705132, COSV66307082; called by muse, mutect2, varscan2
- ADAMTS9 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 83/227 reads (37%) | catalogued as COSV55781008; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1418C>A p.T473N | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV54438162; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 113/194 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as rs370505336; called by muse, mutect2, varscan2
- ADCK2 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 41/245 reads (17%) | catalogued as COSV50781469; called by muse, mutect2, varscan2
- ADCY10 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63242577; called by muse, mutect2, varscan2
- ADCY4 | c.2503G>T p.E835* | Nonsense Mutation (SNP) | VAF 62/195 reads (32%) | catalogued as COSV60254129; called by muse, mutect2, varscan2
- ADD2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100036774, COSV52455725; called by muse, mutect2, varscan2
- ADGB | c.2530C>A p.L844I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62222796; called by muse, mutect2
- ADGB | c.3351G>T p.K1117N | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100828353; called by muse, mutect2
- ADGB | c.3592G>T p.E1198* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV62227732; called by mutect2, varscan2
- ADGB | c.4595G>A p.R1532Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs746595057, COSV58852102; called by muse, mutect2, varscan2
- ADGB | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as rs775573516, COSV58846697; called by muse, mutect2, varscan2
- ADGRA3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1165791849, COSV51563231; called by muse, mutect2, varscan2
- ADGRB2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.891); catalogued as rs1236017996; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by muse, mutect2, varscan2
- ADGRB3 | c.1935C>A p.F645L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65394003; called by muse, mutect2, varscan2
- ADGRB3 | c.2939G>A p.R980K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53260222; called by muse, varscan2
- ADGRE1 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51674946; called by muse, mutect2, varscan2
- ADGRE1 | c.1118T>G p.L373R | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV51677403; called by muse, mutect2, varscan2
- ADGRF2 | c.414G>T p.K138N (on ENST00000296862 / NM_001368115.2; = p.K70N on NM_153839.7) | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1475433057, COSV57287502; called by muse, mutect2, varscan2
- ADGRG4 | c.1494G>T p.M498I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99795898; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRG4 | c.5014G>T p.V1672L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs200165046; called by mutect2, varscan2
- ADGRG6 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51586928; called by muse, mutect2, varscan2
- ADGRG7 | c.1968G>T p.Q656H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs764538012, COSV56299025; called by mutect2, varscan2
- ADGRL3 | c.2297-1G>T p.X766_splice (on ENST00000506720 / NM_001322402.2; = p.X698_splice on NM_015236.6) | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as COSV72230192; called by muse, mutect2, varscan2
- ADGRL4 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs368339256; called by muse, mutect2, varscan2
- ADGRV1 | c.8481T>G p.N2827K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67996579; called by muse, mutect2, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV67977934; called by muse, mutect2, varscan2
- AEBP1 | c.1794G>T p.K598N | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99789013; called by muse, mutect2
- AFDN | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 68/161 reads (42%) | catalogued as rs778113186, COSV60038899; called by muse, mutect2, varscan2
- AFDN | c.3838C>T p.R1280* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs1326466203, COSV60038994; called by muse, mutect2, varscan2
- AFF1 | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867215989, COSV57119983; called by muse, mutect2
- AFF2 | c.956C>A p.S319* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV100651071; called by muse, mutect2, varscan2
- AFF2 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs782144498, COSV53988390; called by muse, mutect2, varscan2
- AFF4 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746618863, COSV54794315; called by muse, mutect2, varscan2
- AFF4 | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as rs1337466139, COSV54792531; called by muse, mutect2, varscan2
- AFM | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768923786, COSV56921130; called by muse, varscan2
- AFM | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV56919366; called by muse, varscan2
- AFP | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV56924278, COSV99890056; called by muse, mutect2, varscan2
- AFTPH | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.804); catalogued as COSV99480262; called by muse, varscan2
- AGAP1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs200056479; called by muse, varscan2
- AGAP1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV58325321; called by muse, mutect2, varscan2
- AGBL1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.457); catalogued as rs751237894; called by muse, mutect2, varscan2
- AGBL5 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs778548414, COSV64079455; called by muse, mutect2, varscan2
- AGGF1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs751143437, COSV57229732; called by muse, varscan2
- AGL | c.4261G>T p.D1421Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750525703; called by muse, mutect2
- AGMO | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs752295082, COSV61118872; called by mutect2, varscan2
- AGMO | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100693957; called by muse, mutect2, varscan2
- AGO2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99596045; called by muse, mutect2, varscan2
- AGPS | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs1372190083, COSV51561302; called by muse, varscan2
- AGTPBP1 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs776488610; called by muse, varscan2
- AGTR1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as rs1417391173, COSV62557140; called by muse, mutect2, varscan2
- AGXT | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs569680503, COSV56755043; called by muse, mutect2, varscan2
- AHI1 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99663659; called by muse, mutect2, varscan2
- AHI1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs192524061, COSV55631489; called by muse, mutect2, varscan2
- AHNAK | c.6890G>A p.G2297D | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs562582236; called by muse, mutect2, varscan2
- AHNAK2 | c.14350C>A p.L4784I | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV100317522, COSV60931888; called by muse, mutect2, varscan2
- AHNAK2 | c.6893C>T p.A2298V | Missense Mutation (SNP) | VAF 229/640 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.24); catalogued as rs780710267, COSV60920631; called by muse, mutect2, varscan2
- AHNAK2 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 240/670 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs375305203; called by muse, mutect2, varscan2
- AHRR | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs753746552; called by muse, mutect2, varscan2
- AIFM2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775593494; called by muse, mutect2, varscan2
- AIMP1 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as rs1406124387; called by muse, mutect2, varscan2
- AK5 | c.485C>A p.S162Y (on ENST00000354567 / NM_174858.3; = p.S136Y on NM_012093.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222950271, COSV100481494; called by muse, mutect2, varscan2
- AK7 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs368611874; called by muse, mutect2, varscan2
- AKAP12 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53570222; called by muse, mutect2, varscan2
- AKAP12 | c.897C>A p.F299L | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs1317071422; called by muse, mutect2, varscan2
- AKAP12 | c.5021C>A p.S1674Y | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV99482290; called by muse, mutect2, varscan2
- AKAP17A | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1317130302; called by muse, mutect2, varscan2
- AKAP4 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100654103, COSV62074891; called by muse, mutect2, varscan2
- AKAP6 | c.4814G>T p.S1605I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55223791; called by muse, mutect2, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, mutect2, varscan2
- AKAP9 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs758729015, COSV62344777; called by muse, mutect2, varscan2
- AKAP9 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1490879515; called by muse, mutect2, varscan2
- AKAP9 | c.7717G>T p.E2573* (on ENST00000359028; = p.E2549* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/129 reads (41%) | catalogued as COSV62338776; called by muse, mutect2, varscan2
- AKNA | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs538104865; called by muse, mutect2, varscan2
- AKNA | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56311715; called by muse, mutect2, varscan2
- AKT3 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV55606314; called by muse, mutect2, varscan2
- AKT3 | c.860T>G p.I287S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55632534; called by muse, mutect2, varscan2
- AKT3 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55625440, COSV55631470; called by muse, mutect2, varscan2
- AL121899.2 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1331369046; called by muse, mutect2, varscan2
- AL121899.2 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.053); catalogued as rs201479752, COSV67350250; called by muse, mutect2, varscan2
- ALB | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs754953092, CM141971, COSV55743097, COSV99890418; called by muse, mutect2, varscan2
- ALDH1A2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs201593015; called by muse, varscan2
- ALDH3A2 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51567286; called by muse, mutect2, varscan2
- ALDH3B2 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1358070944; called by muse, mutect2, varscan2
- ALDOB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 118/292 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812270, COSV66398262; called by muse, mutect2, varscan2
- ALK | c.2602C>A p.L868I | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV101201094; called by muse, mutect2, varscan2
- ALK | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 32/595 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV66593358; called by muse, mutect2
- ALLC | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs376178731, COSV52994643; called by muse, mutect2, varscan2
- ALMS1 | c.6827G>A p.R2276Q | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs200979896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs370447055; called by muse, mutect2, varscan2
- ALOX5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs771513019, COSV65552457; called by muse, mutect2, varscan2
- ALOXE3 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200286114; called by muse, mutect2, varscan2
- ALPK2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs763980190, COSV64489989; called by muse, varscan2
- ALPK3 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as rs115195927, COSV51937611, COSV99360974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPP | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754829627; called by mutect2, varscan2
- ALS2 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as rs750941149; called by muse, mutect2, varscan2
- ALS2 | c.2176T>G p.L726V | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); catalogued as rs1234085357; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, varscan2
- AMER2 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1203169511, COSV63436417; called by muse, mutect2, varscan2
- AMIGO2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56973669; called by muse, mutect2, varscan2
- AMMECR1L | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 102/304 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55761756; called by muse, mutect2, varscan2
- AMOTL1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV54416489; called by muse, mutect2
- AMPD1 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs531229976, COSV62417271; called by muse, mutect2, varscan2
- AMY2A | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879420983, COSV70214849; called by muse, mutect2, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 88/710 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, varscan2
- ANGPT1 | c.1437C>A p.F479L | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV52436455; called by muse, varscan2
- ANGPTL1 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52368198; called by muse, varscan2
- ANK2 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 48/97 reads (49%) | catalogued as CM124411; called by muse, mutect2, varscan2
- ANK2 | c.7964C>T p.S2655L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs373153154, COSV52147308; ClinVar: uncertain significance; called by muse, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANK3 | c.3628C>T p.R1210W (on ENST00000280772 / NM_001320874.2; = p.R344W on NM_001149.3) | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55084035; called by muse, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 60/192 reads (31%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2
- ANK3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267602542, COSV55046002, COSV99777574; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5094G>T p.K1698N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51855942; called by muse, varscan2
- ANKK1 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs1447155082; called by muse, mutect2, varscan2
- ANKRD11 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1323661347, COSV56359151; called by muse, mutect2, varscan2
- ANKRD12 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV104383128; called by muse, mutect2, varscan2
- ANKRD12 | c.3764C>A p.S1255Y | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50847464; called by muse, mutect2, varscan2
- ANKRD12 | c.4598C>T p.S1533F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as rs752111030; called by muse, mutect2, varscan2
- ANKRD17 | c.4673G>T p.R1558I | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58218291; called by muse, varscan2
- ANKRD18B | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as COSV52086652, COSV52087926; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2066C>A p.S689* | Nonsense Mutation (SNP) | VAF 72/276 reads (26%) | catalogued as COSV62004516; called by muse, varscan2
- ANKRD26 | c.4938G>T p.E1646D | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101063252, COSV65774544; called by muse, mutect2, varscan2
- ANKRD26 | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV65777495; called by muse, varscan2
- ANKRD30A | c.2051C>A p.S684Y (on ENST00000611781; = p.S628Y on NM_052997.2) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.888); catalogued as COSV64607318, COSV64611712; called by muse, mutect2, varscan2
- ANKRD30B | c.958C>A p.L320M | Missense Mutation (SNP) | VAF 114/335 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV62813542; called by muse, varscan2
- ANKRD30B | c.2523G>T p.Q841H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.183); catalogued as COSV57702796; called by muse, mutect2, varscan2
- ANKRD31 | c.3896G>T p.R1299I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1388284762; called by muse, mutect2
- ANKRD34B | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 45/102 reads (44%) | catalogued as COSV58613539; called by muse, varscan2
- ANKRD34B | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV58614539; called by muse, varscan2
- ANKRD36 | c.2664G>T p.E888D | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV70734482; called by muse, mutect2, varscan2
- ANKRD36B | c.2919G>T p.K973N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs200935570; called by mutect2, varscan2
- ANKRD36C | c.3007G>T p.D1003Y | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1234712129; called by muse, mutect2, varscan2
- ANKRD49 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs767511021, COSV57060117; called by mutect2, varscan2
- ANKRD53 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs782260627; called by muse, mutect2, varscan2
- ANKRD55 | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV61944514; called by muse, mutect2, varscan2
- ANKRD55 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1206760744; called by muse, mutect2, varscan2
- ANKRD6 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.919); catalogued as rs766916625; called by muse, mutect2, varscan2
- ANKRD62 | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as rs1324827046; called by muse, mutect2, varscan2
- ANKRD63 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.316); catalogued as rs939665080; called by muse, mutect2, varscan2
- ANKS1A | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 133/562 reads (24%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.952); catalogued as COSV64462398; called by muse, mutect2, varscan2
- ANKS1A | c.2905C>T p.R969W | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200225104; called by muse, mutect2, varscan2
- ANKS4B | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs755676619; called by muse, mutect2
- ANKZF1 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1180370499; called by muse, mutect2, varscan2
- ANO1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs375036373; called by muse, mutect2, varscan2
- ANO3 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs763228921, COSV56785203; called by muse, mutect2, varscan2
- ANO4 | c.926G>A p.R309Q (on ENST00000392977 / NM_001286615.2; = p.R274Q on NM_178826.4) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757024624, COSV100152812, COSV100153324; called by muse, mutect2, varscan2
- ANO4 | c.2544C>A p.F848L (on ENST00000392977 / NM_001286615.2; = p.F813L on NM_178826.4) | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54591783; called by muse, mutect2
- ANO5 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61087838; called by muse, mutect2, varscan2
- ANO5 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV61083708; called by muse, mutect2
- ANO5 | c.1704T>G p.F568L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.345); catalogued as COSV61081943; called by muse, mutect2, varscan2
- ANO5 | c.2658G>T p.E886D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100201294; called by muse, mutect2, varscan2
- ANP32E | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100029753, COSV58481613; called by muse, mutect2, varscan2
- ANXA5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396794753, COSV56640132; called by muse, mutect2, varscan2
- AOC2 | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs201376481; called by muse, mutect2, varscan2
- AOX1 | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV65980312; called by muse, mutect2
- AP1G2 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as rs1376624296; called by muse, varscan2
- AP1G2 | c.2018T>G p.F673C | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs779464524, COSV55339722; called by muse, varscan2
- AP2B1 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs866490869; called by muse, mutect2, varscan2
- AP3B2 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 203/342 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1397960537; called by muse, mutect2, varscan2
- AP3M1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1210608288; called by muse, mutect2, varscan2
- APAF1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54489317; called by muse, mutect2, varscan2
- APBA3 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs548949116, COSV57462096; called by muse, mutect2, varscan2
- APBB1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs775846607, COSV54966759; called by muse, mutect2, varscan2
- APBB1IP | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as rs1173507704, COSV66132392; called by muse, varscan2
- APBB2 | c.1585C>T p.R529* (on ENST00000295974 / NM_001166050.2; = p.R530* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as rs757146916, COSV55946364; called by muse, mutect2, varscan2
- APC | c.5565T>G p.C1855W | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57395695; called by muse, mutect2, varscan2
- APC | c.6293A>G p.N2098S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57361473; called by muse, varscan2
- APC | c.6386C>T p.S2129L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782301, COSV57351274, COSV99971525; ClinVar: uncertain significance; called by muse, varscan2
- APEX2 | c.41G>T p.R14I | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs940700336; called by muse, varscan2
- APH1A | c.625T>C p.W209R | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99354398; called by muse, mutect2, varscan2
- APOA5 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV57062765; called by muse, mutect2, varscan2
- APOB | c.11453C>A p.S3818Y | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs749178868, COSV51958917; called by muse, mutect2, varscan2
- APOB | c.11230C>A p.L3744I | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.67); PolyPhen benign (0.297); catalogued as COSV51928541; called by muse, mutect2, varscan2
- APOB | c.9849C>A p.F3283L | Missense Mutation (SNP) | VAF 119/325 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51936132; called by muse, mutect2, varscan2
- APOB | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51940164, COSV99267469; called by muse, mutect2, varscan2
- APTX | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 90/250 reads (36%) | catalogued as rs765145017; called by muse, mutect2, varscan2
- AQR | c.3817C>A p.L1273I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV50050829; called by muse, mutect2, varscan2
- AR | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218564193, CX116061, COSV65958933; called by muse, mutect2, varscan2
- ARAP1 | c.4276C>T p.R1426* (on ENST00000393609 / NM_001040118.2; = p.R1181* on NM_015242.4) | Nonsense Mutation (SNP) | VAF 102/287 reads (36%) | catalogued as rs759749576, COSV61990739; called by muse, mutect2, varscan2
- ARAP2 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749768011, COSV100395388, COSV58284833; called by muse, mutect2, varscan2
- ARAP2 | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100394791; called by muse, mutect2, varscan2
- ARAP2 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868488856; called by muse, mutect2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2
- ARAP3 | c.3508C>T p.R1170C | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs1318926927; called by muse, mutect2, varscan2
- ARFGEF1 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51613017; called by muse, mutect2, varscan2
- ARG2 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566803283, COSV55777318; called by muse, mutect2, varscan2
- ARHGAP11A | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV64381349; called by muse, mutect2, varscan2
- ARHGAP11A | c.1211G>T p.R404I | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777326303; called by muse, mutect2, varscan2
- ARHGAP15 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs759753435; called by muse, mutect2, varscan2
- ARHGAP17 | c.2545C>T p.R849C (on ENST00000289968 / NM_001006634.3; = p.R771C on NM_018054.6) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs772552729, COSV51509512; called by muse, mutect2, varscan2
- ARHGAP19 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV57392369, COSV57392530, COSV57393591; called by muse, mutect2, varscan2
- ARHGAP20 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.057); catalogued as COSV52821112; called by muse, mutect2, varscan2
- ARHGAP24 | c.1042G>A p.E348K (on ENST00000395184 / NM_001025616.3; = p.E255K on NM_031305.3) | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs755357696; called by muse, mutect2, varscan2
- ARHGAP28 | c.890C>T p.T297M (on ENST00000383472 / NM_001366230.1; = p.T138M on NM_001010000.3) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs765768815; called by muse, varscan2
- ARHGAP30 | c.2909G>A p.R970Q (on ENST00000368013 / NM_001025598.2; = p.R759Q on NM_181720.3) | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as rs780720572, COSV63517792; called by muse, varscan2
- ARHGAP30 | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV63518731; called by muse, mutect2, varscan2
- ARHGAP30 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV63514919, COSV63516176; called by muse, mutect2, varscan2
- ARHGAP31 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 73/253 reads (29%) | catalogued as rs1316151567, COSV99957727; called by muse, mutect2, varscan2
- ARHGAP32 | c.1838C>A p.S613Y (on ENST00000310343 / NM_001378025.1; = p.S264Y on NM_014715.4) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100089135; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 73/176 reads (41%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP36 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV52264412; called by muse, varscan2
- ARHGAP36 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as rs866578619, COSV99357958; called by muse, varscan2
- ARHGAP36 | c.678G>A p.M226I | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs778740792, COSV52267139; called by muse, mutect2, varscan2
- ARHGAP36 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 38/58 reads (66%) | catalogued as COSV52265620; called by muse, mutect2, varscan2
- ARHGAP5 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV61534005; called by muse, varscan2
- ARHGAP6 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57304430; called by muse, varscan2
- ARHGEF10 | c.1498G>A p.D500N (on ENST00000398564; = p.D475N on NM_014629.4) | Missense Mutation (SNP) | VAF 134/388 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372895762; called by muse, mutect2, varscan2
- ARHGEF10L | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.699); catalogued as rs575089352; called by muse, mutect2, varscan2
- ARHGEF12 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV63102487; called by muse, mutect2, varscan2
- ARHGEF12 | c.4216G>A p.D1406N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as rs1307381716, COSV100754749; called by muse, mutect2, varscan2
- ARHGEF16 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 151/362 reads (42%) | catalogued as rs777897887, COSV65683650; called by muse, mutect2, varscan2
- ARHGEF28 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.905); catalogued as rs375756705, COSV55251604; called by muse, mutect2, varscan2
- ARHGEF33 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV67257818; called by muse, mutect2, varscan2
- ARHGEF4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs770753604, COSV58123831; called by muse, mutect2, varscan2
- ARHGEF9 | c.1300+2T>G p.X434_splice | Splice Site (SNP) | VAF 29/62 reads (47%) | catalogued as CS1211524; called by muse, mutect2, varscan2
- ARID2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57596407; called by muse, mutect2, varscan2
- ARID3B | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV60559080; called by muse, mutect2
- ARID3B | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1326379631, COSV60558366; called by muse, varscan2
- ARID4B | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 74/217 reads (34%) | catalogued as COSV51599089; called by muse, mutect2, varscan2
- ARL3 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.876); catalogued as COSV53301263; called by muse, mutect2, varscan2
- ARMC10 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60393408; called by muse, varscan2
- ARMC2 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 208/375 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs781413999; called by muse, mutect2, varscan2
- ARMC3 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1021320309, COSV53067927; called by muse, mutect2, varscan2
- ARMC4 | c.2840C>A p.S947* | Nonsense Mutation (SNP) | VAF 95/286 reads (33%) | catalogued as rs1180408667; called by muse, mutect2, varscan2
- ARMC4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs995517847; called by muse, mutect2, varscan2
- ARMC4 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53462652, COSV99518710; called by muse, varscan2
- ARMH2 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as rs572082431; called by muse, mutect2, varscan2
- ARNT2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs370262135; called by muse, mutect2, varscan2
- ARPP21 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.84); catalogued as COSV99490735; called by muse, mutect2, varscan2
- ARR3 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.435); catalogued as rs778493881, COSV57203793; called by muse, mutect2, varscan2
- ASAP2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.457); catalogued as rs1051207873; called by muse, varscan2
- ASAP2 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55631966; called by muse, mutect2, varscan2
- ASAP2 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV53005984; called by muse, mutect2, varscan2
- ASAP3 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768226542, COSV60874029; called by muse, mutect2, varscan2
- ASB15 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs772334400, COSV51924461; called by muse, mutect2, varscan2
- ASCC1 | c.850C>T p.R284* (on ENST00000342444 / NM_001369085.1; = p.R256* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 52/143 reads (36%) | catalogued as rs141611243, COSV57729156; called by muse, mutect2, varscan2
- ASH1L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs867128307, COSV64205328; called by muse, mutect2, varscan2
- ASNS | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1283664547, COSV51551389, COSV51552115; called by muse, varscan2
- ASPA | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99279217; called by muse, mutect2, varscan2
- ASPM | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV54128518; called by muse, mutect2
- ASPM | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs749368876; called by muse, mutect2, varscan2
- ASPN | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV65015955, COSV65016337; called by mutect2, varscan2
- ASXL3 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV52467737; called by muse, mutect2
- ASXL3 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV52465149; called by muse, mutect2, varscan2
- ASXL3 | c.636A>C p.K212N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs915221154; called by muse, mutect2, varscan2
- ASXL3 | c.1535T>C p.L512S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99322992; called by muse, varscan2
- ASXL3 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV52482391; called by muse, varscan2
- ASXL3 | c.3497G>T p.R1166I | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV99323183; called by muse, mutect2
- ASXL3 | c.4103G>T p.R1368I | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52458996; called by muse, mutect2, varscan2
- ATAD2 | c.3955C>A p.L1319I | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as rs751897630; called by muse, mutect2, varscan2
- ATAD2B | c.838A>C p.N280H | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV104380921; called by muse, mutect2, varscan2
- ATF3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs371347514; called by muse, mutect2, varscan2
- ATF6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as rs146640460, COSV63408740; called by muse, mutect2, varscan2
- ATF7IP | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV53771644, COSV99661271; called by muse, mutect2, varscan2
- ATG10 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs767240044, COSV56427050, COSV99967303; called by muse, varscan2
- ATG2B | c.4985T>G p.F1662C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55889921; called by muse, mutect2, varscan2
- ATG2B | c.4190G>A p.R1397H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs370147675; called by muse, mutect2, varscan2
- ATG4A | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV57872672; called by muse, varscan2
- ATG5 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs373794853; called by muse, mutect2, varscan2
- ATIC | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 85/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150438200; called by muse, mutect2, varscan2
- ATL3 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs750850786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs76379269; called by muse, varscan2
- ATM | c.6871T>C p.W2291R | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs746815819; ClinVar: uncertain significance; called by muse, varscan2
- ATM | c.8435C>A p.S2812Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.735); catalogued as CD162053, COSV53734098; called by muse, mutect2, varscan2
- ATP10D | c.4208C>A p.T1403N | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs1417337344; called by muse, mutect2, varscan2
- ATP11B | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60029761; called by muse, mutect2, varscan2
- ATP11C | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs147128476, COSV100557301, COSV59568659, COSV59576357; called by muse, mutect2, varscan2
- ATP13A3 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs753872961, COSV55463686; called by muse, varscan2
- ATP1A3 | c.365C>T p.A122V (on ENST00000545399 / NM_001256214.2; = p.A109V on NM_152296.5) | Missense Mutation (SNP) | VAF 173/537 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1568866568, COSV57486973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A1 | c.987G>T p.K329N | Missense Mutation (SNP) | VAF 167/381 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1282701446; called by muse, mutect2, varscan2
- ATP2A2 | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 74/183 reads (40%) | catalogued as COSV57875702; called by muse, mutect2, varscan2
- ATP2B3 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782390562; called by muse, mutect2, varscan2
- ATP2B4 | c.2823C>A p.F941L | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs752873394, COSV58176270; called by muse, mutect2, varscan2
- ATP6V1D | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1382452548; called by muse, mutect2, varscan2
- ATP7A | c.3788C>A p.S1263Y | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100430471; called by muse, varscan2
- ATP8A1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV52531272; called by muse, mutect2, varscan2
- ATP8A2 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99681865; called by muse, mutect2, varscan2
- ATP8B1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760934663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 83/266 reads (31%) | catalogued as rs777333038, COSV59539910; called by muse, mutect2, varscan2
- ATP8B4 | c.803G>T p.S268I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV52721620; called by muse, mutect2, varscan2
- ATRX | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64871810, COSV64872548; called by muse, varscan2
- ATRX | c.4450C>A p.L1484I | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as COSV64878316; called by muse, varscan2
- ATRX | c.2692G>T p.D898Y | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV100970491, COSV64877609, COSV64882870; called by muse, mutect2
- ATRX | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV64875166, COSV64883207; called by muse, mutect2, varscan2
- ATXN2L | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1364019012, COSV57367575; called by muse, mutect2, varscan2
- AUP1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs755973491, COSV51206410; called by muse, mutect2, varscan2
- AUP1 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs368321899; called by muse, mutect2, varscan2
- AVPR1A | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs761842296, COSV54545596; called by muse, varscan2
- AXDND1 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs781001862; called by muse, mutect2, varscan2
- B3GALT2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs767764174, COSV66463911; called by muse, varscan2
- B3GALT2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as rs751156224, COSV66463997; called by muse, varscan2
- B4GAT1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1188082765, COSV60820157; called by muse, mutect2, varscan2
- BAG6 | c.2297G>A p.S766N (on ENST00000676571; = p.S719N on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 251/439 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245813577, COSV52990065; called by muse, mutect2, varscan2
- BANK1 | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs759883744; called by muse, mutect2, varscan2
- BARD1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs876658999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARHL2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1368225692; called by muse, varscan2
- BAZ1B | c.2398G>T p.E800* | Nonsense Mutation (SNP) | VAF 28/176 reads (16%) | catalogued as COSV100289720; called by muse, mutect2, varscan2
- BAZ2A | c.3334C>T p.R1112W | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752773077, COSV99466827; called by muse, mutect2, varscan2
- BAZ2B | c.4360G>T p.D1454Y | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58599154; called by muse, mutect2, varscan2
- BAZ2B | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as rs778391584, COSV58612205; called by muse, mutect2, varscan2
- BBS10 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs1178651478; called by muse, mutect2, varscan2
- BBS4 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758032659; called by muse, mutect2, varscan2
- BBS9 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs774401569, COSV99625196; called by muse, mutect2, varscan2
- BBX | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57878508; called by muse, mutect2, varscan2
- BBX | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 49/177 reads (28%) | catalogued as COSV57879603; called by muse, mutect2, varscan2
- BCKDHB | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs933828560, COSV57511238; called by muse, mutect2, varscan2
- BCL11A | c.451C>A p.L151I (on ENST00000335712 / NM_001365609.1; = p.L185I on NM_018014.4) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59633815; called by muse, mutect2, varscan2
- BCL2L15 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV63643420; called by muse, mutect2, varscan2
- BCL6 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); catalogued as rs147650939; called by muse, mutect2, varscan2
- BCL9 | c.3761G>A p.R1254Q | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs782430533; called by muse, mutect2, varscan2
- BCLAF3 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV61413252; called by muse, mutect2, varscan2
- BCO2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754125457, COSV63065130; called by muse, mutect2, varscan2
- BCO2 | c.1229G>T p.R410M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63062929; called by muse, mutect2, varscan2
- BCOR | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs527732438, COSV60707971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCORL1 | c.2833C>T p.R945* | Nonsense Mutation (SNP) | VAF 83/134 reads (62%) | catalogued as COSV54390955, COSV54395969; called by muse, mutect2, varscan2
- BCS1L | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs775817146; called by muse, mutect2, varscan2
- BDKRB2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs749848603, COSV60014025; called by muse, mutect2, varscan2
- BEND5 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1244423678, COSV65718609; called by muse, mutect2, varscan2
- BFAR | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 192/501 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as rs779741640, COSV55492918; called by muse, mutect2, varscan2
- BFAR | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs772889819, COSV55494718; called by muse, mutect2, varscan2
- BFSP1 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.546); catalogued as rs374265750; called by muse, mutect2, varscan2
- BHMT | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs372610894; called by muse, mutect2, varscan2
- BIN2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV57207805, COSV99909122; called by muse, mutect2, varscan2
- BIRC2 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1451479658; called by muse, mutect2, varscan2
- BIRC3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54815220; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747957305, COSV63247494; called by muse, mutect2, varscan2
- BLNK | c.1343G>T p.R448I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99813941; called by muse, mutect2, varscan2
- BLOC1S6 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1415748622; called by muse, varscan2
- BLZF1 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1252405250, COSV61392922; called by muse, mutect2, varscan2
- BMERB1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as rs371464387, COSV55505605; called by muse, mutect2, varscan2
- BMP2K | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs754970059, COSV55008366; called by mutect2, varscan2
- BMP4 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV55416792; called by muse, varscan2
- BMPER | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 143/418 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99780718; called by muse, mutect2, varscan2
- BMS1 | c.3647C>T p.T1216M | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773249299; called by muse, mutect2, varscan2
- BMX | c.1371C>A p.F457L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754428384, COSV59590089; called by muse, mutect2, varscan2
- BMX | c.1439C>A p.S480* | Nonsense Mutation (SNP) | VAF 21/140 reads (15%) | catalogued as COSV100564317; called by muse, mutect2, varscan2
- BOD1L1 | c.8908C>T p.R2970C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs775550481, COSV50068860; called by muse, mutect2
- BOD1L1 | c.6943C>T p.R2315W | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs748680457; called by muse, mutect2, varscan2
- BOP1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 153/429 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1167544992; called by muse, mutect2, varscan2
- BPIFA3 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64926054; called by muse, mutect2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 29/92 reads (32%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2
- BPTF | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV58835826; called by muse, varscan2
- BPTF | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV58832361; called by muse, varscan2
- BRAF | c.1403C>A p.S468* (on ENST00000288602 / NM_001374244.1; = p.S428* on NM_004333.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 36/186 reads (19%) | catalogued as COSV56113934, COSV56155642; called by muse, varscan2
- BRCA1 | c.5177G>T p.R1726I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs786203547, COSV58792001; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- BRCA2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs375125172; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.5386G>T p.D1796Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1064793715, COSV66460693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs28897761, COSV66337145; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, varscan2
- BRD1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 103/247 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs762230069, COSV53454612; called by muse, mutect2, varscan2
- BRDT | c.736A>C p.K246Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV62863940; called by muse, mutect2, varscan2
- BRDT | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as COSV62863572, COSV62867237; called by muse, mutect2, varscan2
- BRINP1 | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV56315925; called by muse, mutect2, varscan2
- BRIP1 | c.2674C>A p.L892I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51995505; called by muse, mutect2, varscan2
- BRIP1 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs565458815, COSV51995020; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRWD3 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 53/110 reads (48%) | catalogued as COSV64746018; called by muse, mutect2, varscan2
- BRWD3 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV64749640; called by muse, mutect2, varscan2
- BTAF1 | c.3037C>A p.L1013I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1451126230; called by muse, mutect2, varscan2
- BTBD7 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1351481232; called by muse, mutect2, varscan2
- BTBD9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760705861; called by muse, mutect2, varscan2
- BTC | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs782271380, COSV67547196; called by muse, mutect2, varscan2
- BTN3A3 | c.731G>T p.S244I | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV55070870; called by muse, mutect2
- BTNL9 | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59793626; called by muse, mutect2, varscan2
- BTRC | c.219G>T p.K73N (on ENST00000370187 / NM_033637.4; = p.K37N on NM_003939.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.775); catalogued as COSV100926548; called by muse, mutect2, varscan2
- BUB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs975621280, COSV57063381; called by muse, mutect2, varscan2
- BUB1 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs780152061; called by muse, mutect2
- BVES | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.416); catalogued as rs1054696048, COSV58946639; called by muse, mutect2, varscan2
- C10orf105 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs979991212, COSV56465879; called by muse, mutect2, varscan2
- C10orf71 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373861853, COSV60506335; called by muse, mutect2, varscan2
- C10orf88 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.091); catalogued as COSV64403562, COSV64403801; called by muse, mutect2, varscan2
- C11orf97 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101604905; called by muse, mutect2, varscan2
- C12orf4 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs781358792, COSV54206030; called by muse, mutect2, varscan2
- C12orf40 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760100213, COSV61129961; called by muse, mutect2, varscan2
- C12orf42 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs186161266; called by muse, mutect2, varscan2
- C12orf54 | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1052300938, COSV58359864; called by muse, mutect2
- C12orf66 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as COSV61324790; called by muse, mutect2, varscan2
- C14orf28 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs773957213, COSV57333887; called by muse, mutect2, varscan2
- C14orf39 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147627198, COSV58779891; called by muse, mutect2, varscan2
- C14orf39 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV58779384, COSV58782324; called by muse, mutect2, varscan2
- C16orf95 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.171); catalogued as rs748603129, COSV99497790; called by muse, mutect2, varscan2
- C16orf96 | c.2274A>C p.Q758H | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV101474564; called by muse, mutect2, varscan2
- C19orf44 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773237666, COSV55610825; called by muse, mutect2, varscan2
- C19orf57 | c.289-1G>T p.X97_splice | Splice Site (SNP) | VAF 41/110 reads (37%) | catalogued as COSV100694598; called by muse, mutect2, varscan2
- C1GALT1C1L | c.159C>A p.F53L | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.453); catalogued as rs960128763; called by muse, mutect2, varscan2
- C1R | c.810+1G>T p.X270_splice (on ENST00000536053 / NM_001354346.2; = p.X256_splice on NM_001733.7) | Splice Site (SNP) | VAF 44/122 reads (36%) | catalogued as COSV101599222; called by muse, mutect2, varscan2
- C1orf100 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs144063808; called by muse, mutect2, varscan2
- C1orf105 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV51129632; called by muse, mutect2, varscan2
- C1orf112 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs371455881; called by muse, mutect2
- C1orf141 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV63992007; called by muse, varscan2
- C1orf141 | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV63993474; called by muse, mutect2
- C2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 300/533 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147553278; called by muse, mutect2, varscan2
- C22orf23 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | catalogued as rs564782353; called by muse, mutect2, varscan2
- C2CD5 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61722731; called by muse, mutect2, varscan2
- C2orf73 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58310262; called by muse, mutect2, varscan2
- C3orf52 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1287213408, COSV53496259; called by muse, varscan2
- C3orf62 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 92/464 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs765399300; called by muse, mutect2, varscan2
- C3orf70 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100621362; called by muse, mutect2
- C4B | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1438112943, COSV101426196; called by mutect2, varscan2
- C5 | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs751977981; called by muse, mutect2, varscan2
- C5 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs373359894, CM143546; ClinVar: affects; called by muse, mutect2, varscan2
- C5orf24 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 115/265 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV57542824; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2, varscan2
- C6 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV54712510; called by muse, mutect2
- C6orf118 | c.1303-1G>A p.X435_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as rs767449491; called by muse, mutect2, varscan2
- C6orf89 | c.902G>A p.R301Q (on ENST00000373685; = p.R308Q on NM_152734.4) | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.643); catalogued as rs751486634, COSV62101021; called by muse, mutect2, varscan2
- C7 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs192679722, COSV57480739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C7orf25 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 54/138 reads (39%) | catalogued as rs748828670; called by muse, mutect2, varscan2
- C7orf31 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as rs776399566, COSV52217125, COSV52220311; called by muse, mutect2, varscan2
- C8orf34 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV61389054; called by muse, mutect2, varscan2
- C8orf34 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57409594; called by muse, mutect2, varscan2
- C9orf131 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs749130959; called by muse, mutect2, varscan2
- C9orf135 | c.587G>T p.R196I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021086964; called by muse, mutect2, varscan2
- C9orf43 | c.467G>T p.R156I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs138296577; called by muse, varscan2
- C9orf43 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV55912439; called by muse, varscan2
- CA10 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs765253021, COSV53337234; called by muse, mutect2, varscan2
- CAAP1 | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.509); catalogued as COSV100445193; called by muse, mutect2, varscan2
- CABIN1 | c.4885C>T p.L1629F | Missense Mutation (SNP) | VAF 224/616 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54085501; called by muse, mutect2, varscan2
- CACNA1B | c.4222G>A p.V1408I | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776836911; called by muse, mutect2, varscan2
- CACNA1C | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs907730518; called by muse, mutect2, varscan2
- CACNA1G | c.3888G>T p.E1296D | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61739136; called by muse, mutect2, varscan2
- CACNA1H | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1198273560; called by muse, mutect2, varscan2
- CACNA2D3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55527076; called by muse, mutect2, varscan2
- CACNA2D4 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs200636614, COSV54949212; called by muse, mutect2, varscan2
- CACNA2D4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1372674469, COSV54948209; called by muse, mutect2, varscan2
- CACNG4 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 116/329 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs747138146, COSV50924290, COSV50926382; called by muse, mutect2, varscan2
- CADPS | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV99336323; called by muse, mutect2, varscan2
- CADPS2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57356335; called by muse, mutect2, varscan2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 112/290 reads (39%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CALR | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1031122373; called by muse, mutect2, varscan2
- CALR3 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV54168862; called by muse, varscan2
- CAMK1D | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs762894154; called by muse, mutect2, varscan2
- CAMK4 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 19/28 reads (68%) | catalogued as COSV56680349; called by muse, mutect2, varscan2
- CAMLG | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | catalogued as rs1255711307, COSV51804357; called by muse, mutect2, varscan2
- CAMSAP1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1265391740, COSV56719110; called by muse, mutect2, varscan2
- CAMSAP2 | c.3964C>T p.R1322C (on ENST00000236925 / NM_001297707.2; = p.R1311C on NM_203459.3) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs140682641; called by muse, mutect2, varscan2
- CAPN10 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 105/326 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1349956538; called by muse, mutect2, varscan2
- CAPN13 | c.1222T>G p.F408V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs377435812; called by muse, varscan2
- CAPN13 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs781678089, COSV54428356; called by muse, varscan2
- CAPN13 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1316584552, COSV54429306; called by muse, mutect2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN7 | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as rs761658012; called by mutect2, varscan2
- CAPN9 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748908964; called by muse, varscan2
- CAPN9 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55236660; called by muse, varscan2
- CAPRIN2 | c.2882G>T p.G961V | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368158820; called by muse, varscan2
- CAPRIN2 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV51834002; called by muse, varscan2
- CAPS2 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs201652520; called by muse, mutect2, varscan2
- CAPS2 | c.1221-1G>A p.X407_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV60825209; called by muse, varscan2
- CARD11 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 71/207 reads (34%) | catalogued as COSV67797734; called by muse, mutect2, varscan2
- CARD11 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466997751; called by muse, mutect2, varscan2
- CARD6 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54565329; called by muse, mutect2
- CARMIL1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 128/243 reads (53%) | catalogued as COSV100276554; called by muse, mutect2, varscan2
- CARMIL3 | c.1816C>T p.R606W | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs768549702; called by muse, mutect2, varscan2
- CARNMT1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV65190287; called by muse, mutect2, varscan2
- CASKIN1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1345992121, COSV58870146; called by muse, mutect2, varscan2
- CASP10 | c.1237G>A p.E413K (on ENST00000272879 / NM_032974.5; = p.E370K on NM_001230.5) | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780430275, COSV53777308; called by muse, mutect2, varscan2
- CASP5 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52827895; called by muse, mutect2, varscan2
- CASP8AP2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs753052099, COSV52745086, COSV99386833; called by mutect2, varscan2
- CASR | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs201456938, CM102214, COSV56135659; called by muse, mutect2, varscan2
- CASTOR1 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57577180; called by muse, mutect2, varscan2
- CASZ1 | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 83/254 reads (33%) | catalogued as COSV59739805; called by muse, mutect2, varscan2
- CATSPERD | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101062598; called by muse, varscan2
- CATSPERE | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs41307702, COSV100834963, COSV100835081; called by muse, mutect2, varscan2
- CAVIN4 | c.158G>T p.R53I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1247178831, COSV56866765; called by muse, varscan2
- CAVIN4 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100293145; called by muse, varscan2
- CBL | c.1730A>G p.K577R | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.395); catalogued as rs1342845527; called by muse, mutect2, varscan2
- CBLB | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs561530977; ClinVar: not provided; called by muse, mutect2, varscan2
- CBLC | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.471); catalogued as COSV54323183; called by muse, mutect2, varscan2
- CBLL2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as rs1312930757; called by muse, mutect2, varscan2
- CBLN2 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV54053306; called by muse, mutect2, varscan2
- CC2D2A | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754391657; called by muse, mutect2
- CC2D2A | c.2450T>G p.I817S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as rs766961943; called by muse, varscan2
- CC2D2B | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542746792; called by muse, mutect2, varscan2
- CC2D2B | c.62G>T p.R21I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV60358602; called by muse, mutect2, varscan2
- CCDC105 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as rs1269846265; called by muse, mutect2, varscan2
- CCDC110 | c.2306G>T p.R769L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100293655; called by muse, mutect2, varscan2
- CCDC127 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs779220724; called by muse, mutect2, varscan2
- CCDC134 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs146456593; called by muse, mutect2, varscan2
- CCDC136 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99922721; called by muse, mutect2, varscan2
- CCDC141 | c.2537C>A p.S846Y | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV55368838; called by muse, mutect2, varscan2
- CCDC141 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV55382243; called by muse, mutect2, varscan2
- CCDC141 | c.1499A>C p.K500T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV99837475; called by muse, mutect2
- CCDC144A | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.726); catalogued as COSV100502270; called by muse, mutect2, varscan2
- CCDC144A | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV60696164; called by muse, mutect2, varscan2
- CCDC144A | c.3917C>T p.T1306M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs775402588; called by muse, mutect2, varscan2
- CCDC148 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51771788; called by muse, mutect2
- CCDC168 | c.19711G>T p.E6571* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100487791; called by muse, mutect2
- CCDC168 | c.14209A>G p.T4737A | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.641); catalogued as rs866597092; called by muse, mutect2, varscan2
- CCDC168 | c.5611C>T p.P1871S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as COSV70554768; called by muse, varscan2
- CCDC171 | c.3372G>T p.E1124D | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV52640586, COSV52654276; called by muse, mutect2, varscan2
- CCDC173 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 84/255 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752237900; called by muse, mutect2, varscan2
- CCDC175 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs907096885, COSV55788130; called by muse, mutect2
- CCDC178 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.362); catalogued as COSV55767094; called by muse, mutect2, varscan2
- CCDC181 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV63156153, COSV63156501; called by muse, mutect2
- CCDC181 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376964448; called by muse, mutect2, varscan2
- CCDC185 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as rs942078165; called by muse, mutect2
- CCDC186 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV104427815; called by muse, mutect2, varscan2
- CCDC186 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1461006543, COSV65160531; called by muse, mutect2, varscan2
- CCDC191 | c.611T>G p.L204* | Nonsense Mutation (SNP) | VAF 67/125 reads (54%) | catalogued as rs965643534; called by muse, mutect2, varscan2
- CCDC3 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV66558607; called by muse, mutect2
- CCDC38 | c.1143-1G>T p.X381_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100717594; called by mutect2, varscan2
- CCDC39 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs1332641805, CM131303, COSV56481745; called by mutect2, varscan2
- CCDC40 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 215/567 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs192776296; called by muse, mutect2, varscan2
- CCDC40 | c.3250G>T p.V1084L | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100162822; called by muse, mutect2, varscan2
- CCDC47 | c.1251C>A p.F417L | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as rs1040063367; called by muse, mutect2, varscan2
- CCDC62 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53435438; called by muse, mutect2
- CCDC63 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs377234697; called by muse, mutect2, varscan2
- CCDC65 | c.1206G>T p.E402D | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs1319676255, COSV56739111; called by muse, mutect2, varscan2
- CCDC68 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as rs769350087, COSV61604743; called by muse, mutect2, varscan2
- CCDC7 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs746776900, COSV99511378; called by muse, mutect2, varscan2
- CCDC7 | c.2702C>A p.S901Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.809); catalogued as COSV56536416; called by muse, mutect2, varscan2
- CCDC73 | c.2430G>T p.K810N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58795265; called by mutect2, varscan2
- CCDC73 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58798853; called by muse, mutect2, varscan2
- CCDC74B | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100134724; called by muse, mutect2, varscan2
- CCDC77 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1030728081, COSV53472282, COSV53472571; called by muse, mutect2, varscan2
- CCDC78 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs749614530; called by muse, mutect2, varscan2
- CCDC78 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 231/618 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752010401, COSV52402029, COSV52402846; called by muse, mutect2, varscan2
- CCDC8 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 121/257 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV56773173; called by muse, mutect2, varscan2
- CCDC81 | c.781C>T p.R261* (on ENST00000445632 / NM_001156474.2; = p.R171* on NM_021827.4) | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs1171982662, COSV53581459; called by muse, mutect2, varscan2
- CCDC82 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53593988; called by muse, mutect2, varscan2
- CCDC82 | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53594441; called by muse, mutect2, varscan2
- CCDC88A | c.3452C>A p.S1151Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV99711087; called by muse, mutect2, varscan2
- CCDC88A | c.2135C>A p.S712Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55060261; called by muse, mutect2, varscan2
- CCDC91 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774693971, COSV60347182; called by muse, mutect2
- CCIN | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 233/440 reads (53%) | catalogued as rs201282286; called by muse, mutect2, varscan2
- CCKAR | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs115488558; called by muse, mutect2, varscan2
- CCL11 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs56358892, COSV59924967; called by muse, mutect2, varscan2
- CCN4 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs776694942, COSV51534877; called by muse, mutect2, varscan2
- CCN6 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100037228; called by muse, mutect2, varscan2
- CCNY | c.155-1G>T p.X52_splice | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV55183596; called by muse, varscan2
- CCP110 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs768611357, COSV101195326; called by muse, varscan2
- CCR5 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as COSV52753142; called by muse, mutect2, varscan2
- CCR9 | c.682G>A p.V228M (on ENST00000357632 / NM_031200.3; = p.V216M on NM_006641.4) | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs200677145; called by muse, mutect2, varscan2
- CCSER1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); catalogued as rs1162759832, COSV61418488; called by muse, varscan2
- CCT6B | c.725+1G>A p.X242_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as rs376851436, COSV58489082; called by muse, mutect2, varscan2
- CCT8L2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as rs368569729; called by muse, mutect2, varscan2
- CD164L2 | c.494C>A p.A165D | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100927578; called by muse, mutect2, varscan2
- CD1E | c.1008G>T p.K336N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV100936913; called by muse, mutect2, varscan2
- CD22 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs747460337, COSV50053857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD247 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 186/465 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.705); catalogued as rs757978223, COSV62977297; called by muse, mutect2, varscan2
- CD274 | c.419G>T p.R140I | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV67501951; called by muse, mutect2, varscan2
- CD2AP | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 53/106 reads (50%) | catalogued as COSV100830653; called by muse, mutect2, varscan2
- CD2AP | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199622885, COSV63763227; called by muse, mutect2, varscan2
- CD300C | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.074); catalogued as rs765996056, COSV58170531; called by muse, mutect2, varscan2
- CD36 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99987982; called by muse, mutect2, varscan2
- CD3D | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 101/265 reads (38%) | catalogued as rs1172098673, COSV52673644; called by muse, mutect2, varscan2
- CD46 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs200133631, COSV59734311; called by muse, mutect2, varscan2
- CD6 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 188/448 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs936172100, COSV57839952; called by muse, mutect2, varscan2
- CD79B | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 173/499 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50075959, COSV50076941; called by muse, mutect2, varscan2
- CD83 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100997807; called by muse, mutect2, varscan2
- CD86 | c.364C>T p.R122C (on ENST00000330540 / NM_175862.5; = p.R116C on NM_006889.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as rs770052627, COSV100053903; called by muse, mutect2, varscan2
- CD96 | c.1129C>A p.L377I (on ENST00000283285 / NM_198196.3; = p.L361I on NM_005816.5) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV51919040, COSV51922856; called by muse, mutect2, varscan2
- CDAN1 | c.2615G>T p.R872I | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV62331498; called by muse, mutect2
- CDC123 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs750545764, COSV99827121; called by muse, varscan2
- CDC16 | c.542-1G>T p.X181_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV52957665; called by muse, mutect2, varscan2
- CDC20B | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1296379409; called by muse, varscan2
- CDC20B | c.698-1G>T p.X233_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99697199; called by muse, varscan2
- CDC20B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1008892536, COSV57054773; called by muse, mutect2, varscan2
- CDC25A | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV56770245; called by muse, mutect2, varscan2
- CDC25B | c.275G>A p.R92Q (on ENST00000245960 / NM_021873.3; = p.R78Q on NM_004358.4) | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV99847969; called by muse, mutect2, varscan2
- CDC42BPA | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs773337354; called by muse, mutect2, varscan2
- CDC42BPA | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62007868; called by muse, mutect2, varscan2
- CDC42BPB | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs781414650, COSV100775558; called by muse, mutect2, varscan2
- CDC45 | c.215T>C p.F72S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1262629632; called by muse, mutect2, varscan2
- CDC5L | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV101014876, COSV65177377; called by muse, varscan2
- CDCA2 | c.2049G>T p.M683I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57944935; called by muse, mutect2, varscan2
- CDCA7 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV60720151; called by muse, mutect2
- CDCA7L | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62259193; called by muse, mutect2, varscan2
- CDCA8 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs1247596069; called by muse, mutect2, varscan2
- CDH10 | c.2240C>A p.S747Y | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051396, COSV52588765; called by muse, mutect2, varscan2
- CDH11 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51753294; called by muse, varscan2
- CDH12 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66402345; called by muse, mutect2, varscan2
- CDH15 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.054); catalogued as rs200026741, COSV99228386; called by muse, mutect2, varscan2
- CDH18 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56941936, COSV56945428; called by muse, mutect2, varscan2
- CDH19 | c.1604G>T p.R535I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1245492312, COSV50954545; called by muse, mutect2, varscan2
- CDH6 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as rs774976574, COSV54070709; called by muse, mutect2
- CDH9 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99145090; called by muse, mutect2, varscan2
- CDHR1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 127/181 reads (70%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs201649854; called by muse, mutect2, varscan2
- CDHR1 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 128/367 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV60566637; called by muse, mutect2, varscan2
- CDHR2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1423170637; called by muse, mutect2, varscan2
- CDHR2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770372067, COSV56141837; called by muse, mutect2, varscan2
- CDHR2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs746333783, COSV56135002, COSV56137768; called by muse, mutect2, varscan2
- CDHR3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as rs373691451, COSV58418534; called by muse, mutect2, varscan2
- CDHR5 | c.1576C>T p.P526S (on ENST00000358353 / NM_001171968.2; = p.P532S on NM_021924.5) | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.548); catalogued as rs1228926866, COSV57644375; called by muse, mutect2, varscan2
- CDK13 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as rs150957134, COSV51697681; called by muse, mutect2, varscan2
- CDK16 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1422835444, COSV52092956; called by muse, mutect2, varscan2
- CDK19 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60447395, COSV60451659; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1595G>A p.R532H (on ENST00000357886 / NM_001365728.1; = p.R518H on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs544294285; called by muse, varscan2
- CDK5RAP1 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1229424278; called by muse, mutect2, varscan2
- CDKAL1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as COSV51180282; called by muse, varscan2
- CDKL5 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV101184378; called by muse, varscan2
- CDRT1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1327139893, COSV63052386, COSV63054528; called by muse, mutect2, varscan2
- CDX4 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868321760, COSV65171686; called by muse, mutect2, varscan2
- CDYL | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs372317441; called by muse, varscan2
- CEACAM20 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780618317, COSV100387019; called by muse, mutect2, varscan2
- CEACAM3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1367815305; called by muse, mutect2, varscan2
- CEACAM5 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs199938455; called by muse, mutect2
- CEBPB | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100269977; called by muse, mutect2, varscan2
- CECR2 | c.1657C>T p.R553* (on ENST00000342247 / NM_001290047.2; = p.R370* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV52835896; called by muse, mutect2, varscan2
- CELF4 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 174/502 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58445248; called by muse, mutect2, varscan2
- CELSR1 | c.4547C>T p.P1516L | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766103727, COSV99416255; called by muse, mutect2, varscan2
- CEMIP | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as rs759087523; called by muse, mutect2, varscan2
- CENPF | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs376653860; called by muse, varscan2
- CENPF | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV65272425; called by muse, varscan2
- CENPF | c.6754G>T p.E2252* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV65274967; called by muse, mutect2, varscan2
12,138 further variants in this file (8,605 protein-altering or splice-affecting, 1,988 silent, 1,545 other) are not listed here.
